CGCI case HTMCP-01-10-00778 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1b59613e-0fdb-413f-9714-9ea73561d2ed

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Age at index: 45 years.

Diagnoses (2)
1. Diffuse large B-cell lymphoma, NOS (the primary disease): ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: primary; Age at diagnosis: 45.7 years (16,674 days); Year of diagnosis: 2017; Method of diagnosis: Biopsy; Prior malignancy: yes; Prior treatment: No; Days to last follow up: 414 days (1.1 years); Max tumor bulk site: Cervical lymph nodes.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Cervical, NOS; Lymph nodes positive: 1; Lymph nodes tested: 1; Tumor largest dimension diameter: 20 cm.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Diffuse large B-cell lymphoma, NOS: Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: Prior primary.

Follow-up (3 entries)
- Days to follow up: 0 days; Imaging type: PET; Imaging result: Positive.
- Days to follow up: 129 days; Disease response: With Tumor.
- Days to follow up: 414 days (1.1 years); Disease response: With Tumor; Imaging type: PET; Imaging result: Positive.

Molecular and laboratory tests
- ALK: Normal.
- BCL2 (IHC): Positive.
- BCL2: Normal.
- BCL2: Positive.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- BCL6: Normal.
- BCL6: Positive; Specialized molecular test: BCL6 > 30%.
- CCND1: Normal.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD10: Negative; Specialized molecular test: CD10 > 30%.
- CD138: Negative.
- CD19: Positive.
- CD20 (IHC): Positive.
- CD20: Positive.
- CD3 (IHC): Positive.
- CD5: Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Negative; Specialized molecular test: MUM1 > 30%.
- IRF4: Abnormal, NOS.
- IRF4: Positive; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MALT1: Normal.
- MYC: Normal.
- PAX5: Abnormal, NOS.
- PAX5: Positive.
- REL: Normal.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Test: Abnormal, NOS; Specialized molecular test: Ki-67.
- Test: Abnormal, NOS; Specialized molecular test: MS4A1.
- Test: Normal; Cytoband: 9p21.
- Lactate Dehydrogenase 247 [Blood test normal range upper: 256].
- Epstein-Barr Virus (ISH): Equivocal.
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Day 0: Comorbidities: Varicella Zoster Virus.
- Day 0: Risk factors: Varicella Zoster Virus.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 0: Risk factors: Syphilis.
- Day 0: Weight: 89 kg; Height: 172.7 cm; BMI: 29.8; CD4 count: 322; Haart treatment indicator: Yes; HIV viral load: 26.
- Day 0: Comorbidities: Hepatitis B Infection.
- Day 0: Risk factors: Chlamydia.
- Day 0: Comorbidities: Chlamydia.
- Day 0: Comorbidities: Syphilis.
- Day 0: Risk factors: Hepatitis B Infection.
- Day 0: Comorbidities: Herpes.
- Day 129: Nadir CD4 count: 220.
- Comorbidities: HIV/AIDS.
- Risk factors: HIV/AIDS.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-01-10-00778-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-10-00778-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-10-00778-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Treatment outcome first course: Progressive Disease; Tobacco smoking history indicator: 1; Lost to follow-up: No.
- History of disease: Year of HIV diagnosis: 2003; Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes; Cdc HIV risk group: Homosexual or bisexual contact; History relevant infectious diagnosis: Hepatitis B, chicken pox, HSV infection, chlamydia, syphillis.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Tumor tissue sites: Submitted tumor site: No Known Extranodal Involvement.
- Primary pathology: Method initial path diagnosis: Biopsy (all types); Lymph nodes examined: Yes.
- Tests performed: LDH level: 247; Ebv status malignan cells method: EBER in situ hybridization.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis tested: CD19.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD138.
- Tests performed, Genetic testing results, Genetic testing result 8: Immunophenotypic analysis tested: PAX5.
- Tests performed, Genetic testing results, Genetic testing result 9: Immunophenotypic analysis tested: CD5.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 4: Genetic abnormality tested: ALK.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 5: Genetic abnormality tested: C-rel.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 6: Genetic abnormality tested: 9p21.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 7: Genetic abnormality tested: CCND1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 8: Genetic abnormality tested: MALT1.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 9: Genetic abnormality tested: PAX5.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 10: Genetic abnormality tested: CD20.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 11: Genetic abnormality tested: Ki67; Genetic abnormality results: positive 50-60%.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 12: Genetic abnormality tested: MUM1; Genetic abnormality results: positive weak focal.
- Follow-up form 1: Treatment outcome first course: Progressive Disease; Tumor status: With tumor; New tumor event diagnosis indicator: No.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-10-00778-01A-01D-12280:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-10-00778-01A-01R-12280:
- % tumour top: 90
- % tumour bottom: 90
